Somatic mutation profile of tumor specimen MBCProject_1046_T1_WES (aliquot MBCProject_1046_T1_WES_1) from CMI case MBCProject_1046, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.4 years (12,915 days).
Specimen MBCProject_1046_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29793ca1-60cf-494c-917a-67e1628dbea5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1046_SALIVA (Saliva), aliquot MBCProject_1046_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e298cb3a-43f5-4f69-8043-e626efe8eb9b

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Intron 5, 3'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 35/55 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL5 | c.1243G>A p.V415I (on ENST00000354273; = p.V471I on NM_016234.3) | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs201224468, COSV100634580; called by muse, mutect2, varscan2
- FERMT3 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868019900, COSV99656785; called by muse, mutect2
- GDF2 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs141580368; called by muse, mutect2
- IFNGR2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs142997921; called by muse, mutect2
- IRS4 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs758229056; called by mutect2, varscan2
- ITGA2B | c.2311G>T p.V771L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs368953599, CM139799; called by muse, mutect2, varscan2
- RPS15 | c.392C>G p.P131R | Missense Mutation (SNP) | VAF 47/398 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51830854; called by muse, mutect2, varscan2
- RUNX2 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CD141087; called by muse, mutect2, varscan2
- TAS1R2 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as rs1289495112; called by muse, mutect2
- ZNF696 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.043); catalogued as rs142905790; called by mutect2, varscan2
- ATAD5 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP47 | c.2405T>G p.I802S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CNTNAP1 | c.808C>G p.R270G | Missense Mutation (SNP) | VAF 20/735 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYLD | c.1493A>G p.N498S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- EIF2S3 | c.1181A>G p.K394R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.077); called by muse, varscan2
- IZUMO1 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MED24 | c.2001C>G p.N667K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- MORC4 | c.629_636delinsAAAAAAAA p.I210_G212delinsKKK | Missense Mutation (ONP) | VAF 6/64 reads (9%) | called by mutect2*, pindel
- MRC2 | c.2851_2854del p.K951Afs*44 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- NAMPT | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 51/332 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NDUFB6 | c.257T>C p.M86T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2
- SFSWAP | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- CHD8 | c.4398T>C p.S1466= (on ENST00000646647 / NM_001170629.2; = p.S1187= on NM_020920.4) | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2
- L1CAM | c.1614G>A p.T538= | Silent (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- MFSD13A | c.873G>C p.L291= | Silent (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- OR2A12 | c.609G>T p.A203= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV68821029; called by muse, mutect2, varscan2
- PRR23A | c.375C>T p.D125= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV101270349, COSV101270361; called by muse, mutect2, varscan2
- SLC10A2 | c.870G>A p.P290= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs370310605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNFAIP1 | c.570C>A p.S190= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- CNGA1 | c.-15+10490T>G | Intron (SNP) | VAF 8/63 reads (13%) | catalogued as rs1197725004, COSV104422602; called by muse, mutect2
- CRAT | c.28-748C>T | Intron (SNP) | VAF 8/167 reads (5%) | called by muse, mutect2
- HACD1 | c.257+1311G>C | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- LINC02876 | n.429T>C | RNA (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 7/66 reads (11%) | catalogued as rs1298787056; called by muse, varscan2
- MFSD13A | c.828+659C>T | Intron (SNP) | VAF 8/56 reads (14%) | catalogued as rs963432899, COSV99487997; called by muse, varscan2
- VILL | c.1183-532C>T | Intron (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
